Gene-level copy-number profile of tumor specimen TCGA-DU-7008-01A from TCGA case TCGA-DU-7008, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.9 years (15,289 days).
Specimen TCGA-DU-7008-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.c477fa72-59a6-4753-a9f9-a887a7f21004.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7008-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/267cc5b3-e5d6-48d0-a951-14c31c439572

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 2,384; copy number 3: 6,500; copy number 4: 48,896; copy number 5: 174; copy number 6: 13; copy number 7: 794; copy number 8: 216; copy number 9: 243; copy number 10: 583; copy number 11: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-7008-01A-11D-2023-01): tumor purity 0.83, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 838 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:121,304,657–125,482,966, 60 genes, copy number 9–11 (within-gene range 7–11): AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2, AC004875.1, RN7SKP277, PNPT1P2, PTPRZ1, AASS, RNU7-154P, AC015983.2, AC006020.1, AC015983.1, FEZF1, FEZF1-AS1, CADPS2, AC004594.1, AC006463.1, RPS26P31, RNF133, RNF148, AC004986.1, TAS2R16, AC073311.1, SLC13A1, LYPLA1P1, IQUB, AC073323.1, RNU6-296P, NDUFA5, ASB15, ASB15-AS1, LMOD2, WASL, WASL-DT, RNU6-11P, HYAL6P, HYAL4, SPAM1, AC004690.1, AC004690.2, TMEM229A, AC006148.1, AC006148.2, AC004930.1, SSU72P8, AC005521.1, RNU6-102P, AC004925.1, GPR37, C7orf77, POT1, POT1-AS1, EEF1GP1, LINC02830, AC019155.1, AC019155.2, AC010099.1.
- chr7:125,917,871–159,233,377, 778 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
